Somatic mutation profile of tumor specimen TCGA-IQ-7630-01A (aliquot TCGA-IQ-7630-01A-11D-2078-08) from TCGA case TCGA-IQ-7630, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 49.6 years (18,131 days).
Specimen TCGA-IQ-7630-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aca56820-c795-4903-8dfa-d93240ba404c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IQ-7630-10A (Blood Derived Normal), aliquot TCGA-IQ-7630-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/266ddbc9-1881-4402-8a3e-534a780d65a0

The open-access MAF lists 123 somatic variants for this specimen: 90 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 30, Nonsense Mutation 7, In Frame Del 2, Frame Shift Del 1, Splice Site 1, Splice Region 1, RNA 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- AFG1L | c.761A>G p.N254S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100933941; called by muse, mutect2, varscan2
- ANO5 | c.1103C>T p.T368M | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs760792371, CM1313952, COSV61083437, COSV61089379; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP35 | c.1819G>A p.G607S | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV68334209, COSV68335441; called by muse, mutect2, varscan2
- BIRC7 | c.734G>T p.R245L (on ENST00000217169 / NM_139317.3; = p.R227L on NM_022161.4) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV53900149, COSV99416755; called by muse, mutect2, varscan2
- BPIFB1 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs201145500; called by muse, mutect2, varscan2
- BRIX1 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as rs1048011165, COSV100331413; called by muse, mutect2, varscan2
- CACNA1C | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 78/289 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59698176; called by muse, mutect2, varscan2
- CCDC114 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs200697095; called by muse, mutect2, varscan2
- CDK4 | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99226004; called by muse, mutect2, varscan2
- CEMIP2 | c.3767C>T p.P1256L | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV100987383; called by muse, mutect2, varscan2
- CTNND2 | c.1461G>C p.Q487H | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100476581, COSV100480520; called by muse, mutect2, varscan2
- CUL9 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs543821565, COSV99335405, COSV99335767; called by muse, mutect2, varscan2
- CYP2R1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs782643124, COSV100584920; called by muse, mutect2, varscan2
- DNAH8 | c.5123C>G p.S1708* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as COSV100545329, COSV59469889; called by muse, mutect2, varscan2
- DSCAM | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV68021299; called by muse, mutect2, varscan2
- DUS3L | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1295086525, COSV100288203; called by mutect2, varscan2
- EFL1 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.416); catalogued as rs376049845; called by muse, mutect2, varscan2
- EGFR | c.1762G>A p.G588S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as rs989939484, COSV51792433; called by muse, mutect2, varscan2
- EMC9 | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV99246241; called by muse, mutect2, varscan2
- FAM221A | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100794328; called by muse, mutect2, varscan2
- FAM71A | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs773097173, COSV54236120; called by muse, mutect2, varscan2
- FBXO27 | c.479G>A p.W160* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV99494611; called by muse, mutect2, varscan2
- GALNT3 | c.87C>A p.F29L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV101204941; called by muse, mutect2, varscan2
- GBA3 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs758521024, COSV101545513, COSV72437980; called by muse, mutect2, varscan2
- GNAS | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs553453544, COSV100006534; called by muse, varscan2
- GPLD1 | c.2140C>T p.R714C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs553287827, COSV57754152; called by muse, mutect2, varscan2
- H4C11 | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100747990; called by muse, mutect2, varscan2
- HCFC2 | c.2216C>T p.T739I | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV99983072; called by muse, mutect2
- HES6 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99800746; called by muse, mutect2, varscan2
- HIF3A | c.1966G>A p.G656R (on ENST00000377670 / NM_152795.4; = p.G587R on NM_022462.4) | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs143456536; called by muse, mutect2, varscan2
- HSPG2 | c.2546G>T p.R849L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs749841200, COSV101020692, COSV65978968; called by muse, mutect2, varscan2
- HTR3D | c.1109C>T p.P370L (on ENST00000382489 / NM_001163646.2; = p.P195L on NM_182537.3) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs370663074, COSV100488259; called by muse, mutect2, varscan2
- KAT14 | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV100890074; called by muse, mutect2
- KBTBD12 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs552334735, COSV100675431, COSV59678009; called by muse, mutect2, varscan2
- KCNJ5 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1389808024, COSV57970792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNS2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs765976410, COSV54637047; called by muse, mutect2, varscan2
- KRT14 | c.753_755del p.K251del | In Frame Del (DEL) | VAF 24/110 reads (22%) | catalogued as rs1462355601; called by pindel, varscan2
- L3MBTL3 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.608); catalogued as rs763375416, COSV62384072; called by muse, mutect2, varscan2
- LAMA2 | c.5285G>C p.R1762P | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs138296015, COSV101370451, COSV70355297; called by muse, mutect2, varscan2
- LCT | c.1615A>G p.T539A | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99929498; called by muse, mutect2, varscan2
- LSR | c.1040C>A p.P347H (on ENST00000361790; = p.P328H on NM_015925.6) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99723401; called by muse, mutect2, varscan2
- MAP3K9 | c.1450C>T p.L484F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101173629; called by muse, mutect2, varscan2
- MATN4 | c.805C>T p.H269Y (on ENST00000372754; = p.H228Y on NM_003833.4) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | PolyPhen possibly damaging (0.882); catalogued as COSV100637010; called by muse, mutect2, varscan2
- MIA2 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV54485526; called by muse, mutect2, varscan2
- MYH9 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99338839; called by muse, mutect2, varscan2
- MYO7B | c.4174G>A p.V1392M | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746972907, COSV101268179, COSV67350206; called by muse, mutect2, varscan2
- NAV3 | c.6211G>A p.E2071K (on ENST00000397909 / NM_001024383.2; = p.E2049K on NM_014903.6) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99890987; called by muse, mutect2, varscan2
- NEBL | c.2081G>A p.R694Q | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1443675600, COSV101009211; called by muse, mutect2, varscan2
- NEMF | c.146C>A p.T49K | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV100027658; called by muse, mutect2
- NF2 | c.863C>G p.S288* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV58523216; called by muse, mutect2
- NLRP11 | c.833G>T p.R278M | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100789733; called by muse, mutect2, varscan2
- NOXRED1 | c.788G>C p.S263T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100033091; called by mutect2, varscan2
- NUMA1 | c.4702C>T p.Q1568* | Nonsense Mutation (SNP) | VAF 77/323 reads (24%) | catalogued as COSV100706154; called by muse, mutect2, varscan2
- OR4C6 | c.537G>T p.L179F | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.162); catalogued as COSV58603749; called by muse, mutect2, varscan2
- PAX7 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs373331822, COSV64750609; called by muse, mutect2, varscan2
- PCDHA7 | c.2332C>T p.Q778* | Nonsense Mutation (SNP) | VAF 22/35 reads (63%) | catalogued as COSV100970734; called by muse, mutect2, varscan2
- PCDHGA11 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99538385; called by muse, mutect2, varscan2
- PDSS2 | c.208C>G p.R70G | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100941753, COSV64648435; called by muse, mutect2, varscan2
- PHF20L1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV55198604; called by muse, mutect2, varscan2
- PHKA1 | c.3631G>A p.V1211M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs1025423127, COSV100263190; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLA2G12B | c.416C>G p.S139W | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100888006, COSV65978700; called by muse, mutect2, varscan2
- PLA2G4F | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs138996971; called by muse, mutect2, varscan2
- POPDC3 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 23/135 reads (17%) | catalogued as rs375494032; called by muse, mutect2, varscan2
- PXK | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100244110; called by muse, mutect2, varscan2
- RASA1 | c.2603+1G>T p.X868_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | catalogued as CS083252, COSV99169824; called by muse, varscan2
- RBP3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs150932600; called by muse, mutect2, varscan2
- SHANK2 | c.3454G>A p.E1152K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.501); catalogued as COSV53606315; called by muse, mutect2, varscan2
- SLC15A1 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100918202; called by muse, mutect2
- SLC16A13 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748604375, COSV100338639, COSV57274804; called by muse, mutect2, varscan2
- SLC26A11 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs549132744, COSV63279398; called by muse, varscan2
- SNTG2 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as COSV100422606, COSV100423571, COSV58011512; called by muse, mutect2, varscan2
- SNX24 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as COSV99756060; called by muse, mutect2, varscan2
- SSBP1 | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.223); catalogued as COSV99519779; called by muse, mutect2, varscan2
- TBX21 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.5); catalogued as rs746185082, COSV99455958; called by muse, mutect2, varscan2
- TDP1 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs1193678728, COSV100187813; called by muse, mutect2, varscan2
- TNKS1BP1 | c.158T>G p.L53R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100836032; called by mutect2, varscan2
- TNS2 | c.762G>A p.G254= (on ENST00000314250 / NM_170754.4; = p.G264= on NM_015319.2) | Splice Region (SNP) | VAF 3/20 reads (15%) | catalogued as rs1346766531, COSV100048098; called by muse, mutect2
- TRPC1 | c.1535G>A p.R512H (on ENST00000476941 / NM_001251845.2; = p.R478H on NM_003304.4) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745396101, COSV56422583; called by muse, mutect2, varscan2
- UMOD | c.1636G>T p.G546C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100208362; called by muse, mutect2, varscan2
- VPS13A | c.1205G>A p.R402K | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100652787; called by muse, mutect2, varscan2
- VPS13B | c.6605G>A p.R2202H | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as rs147099791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WNK4 | c.2060G>C p.R687T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99890373; called by muse, mutect2, varscan2
- ZFYVE28 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.714); catalogued as rs145750553; called by muse, mutect2, varscan2
- ZNF23 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs201062958, COSV100612160; called by muse, mutect2, varscan2
- ZNF749 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs368025048; called by muse, mutect2, varscan2
- ALOX15 | c.1125_1130del p.M376_R377del | In Frame Del (DEL) | VAF 7/60 reads (12%) | called by mutect2, pindel*, varscan2*
- ANAPC1 | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by mutect2, varscan2
- SLC9A1 | c.850del p.E284Nfs*13 | Frame Shift Del (DEL) | VAF 25/86 reads (29%) | called by mutect2, pindel, varscan2
- ACOX2 | c.840C>T p.Y280= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs142094321; called by muse, mutect2, varscan2
- ADRB1 | c.546G>A p.V182= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100992282; called by muse, mutect2, varscan2
- C5AR1 | c.687G>A p.T229= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as rs199885491, COSV61893706; called by muse, mutect2, varscan2
- CA8 | c.300G>A p.S100= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs749173414, COSV100526643, COSV58772456; called by muse, mutect2, varscan2
- CHD3 | c.1836G>A p.P612= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs752055513, COSV57882257; called by muse, mutect2, varscan2
- CNGA3 | c.2019G>T p.G673= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs763564632, COSV99736775; called by muse, mutect2, varscan2
- CUX1 | c.1347C>T p.H449= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV99471517; called by muse, mutect2, varscan2
- DYSF | c.1191C>T p.A397= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs769254776, COSV50638053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBLN5 | c.954C>T p.I318= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs755894963, COSV50904258, COSV99969596; called by muse, mutect2, varscan2
- GPR132 | c.105C>T p.N35= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs895826394, COSV100317567; called by muse, mutect2, varscan2
- GPR160 | c.117T>C p.N39= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100576128; called by muse, mutect2, varscan2
- ITGA9 | c.447C>T p.I149= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV99292768; called by muse, mutect2, varscan2
- KCND2 | c.876C>T p.L292= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100475811; called by muse, mutect2, varscan2
- KRBA1 | c.2286G>A p.P762= | Silent (SNP) | VAF 42/174 reads (24%) | catalogued as rs376041143; called by muse, mutect2, varscan2
- LAMP5 | c.771C>T p.H257= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs754004900, COSV55715104; called by muse, mutect2, varscan2
- LHX9 | c.204C>T p.P68= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as rs778635437, COSV100435891; called by muse, mutect2, varscan2
- MYO5A | c.2724C>G p.L908= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100697667; called by muse, mutect2, varscan2
- NR5A2 | c.885G>T p.T295= (on ENST00000367362 / NM_205860.3; = p.T249= on NM_003822.5) | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV52658230, COSV99371133; called by muse, mutect2, varscan2
- PARP16 | c.552C>T p.T184= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV56034878, COSV99975482; called by muse, mutect2
- PAX4 | c.45C>G p.L15= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV100490133; called by muse, mutect2, varscan2
- PTGR2 | c.651C>A p.L217= | Silent (SNP) | VAF 48/170 reads (28%) | catalogued as COSV99966352; called by muse, mutect2, varscan2
- RDH8 | c.66C>T p.A22= (on ENST00000651512; = p.A2= on NM_015725.4) | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs753456089, COSV50676590; called by muse, mutect2, varscan2
- SLC12A4 | c.3039A>G p.Q1013= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs150617520; called by muse, mutect2, varscan2
- SLC15A1 | c.207C>T p.L69= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs768700499, COSV64711886; called by muse, mutect2
- SLC19A3 | c.753C>T p.S251= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV51454686; called by muse, mutect2, varscan2
- SMUG1 | c.444C>T p.L148= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV99679445; called by muse, mutect2, varscan2
- TAL1 | c.465G>A p.P155= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as rs747127107, COSV53747702; called by muse, mutect2, varscan2
- TLN1 | c.297G>A p.T99= | Silent (SNP) | VAF 22/238 reads (9%) | catalogued as rs748628195, COSV100147739; called by muse, mutect2
- TTC27 | c.2142G>A p.L714= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1316193639, COSV100513043; called by muse, mutect2, varscan2
- UNC13B | c.1671C>T p.I557= | Silent (SNP) | VAF 17/315 reads (5%) | catalogued as COSV101036671; called by muse, mutect2
- AL132655.6 | chr20:58840123 G>A | 5'Flank (SNP) | VAF 33/67 reads (49%) | catalogued as rs1323591529, COSV100006531; called by muse, mutect2, varscan2
- CFAP61 | c.567-5362C>T | Intron (SNP) | VAF 17/154 reads (11%) | called by muse, mutect2, varscan2
- SNORD116-20 | n.72A>T | RNA (SNP) | VAF 45/176 reads (26%) | called by muse, mutect2, varscan2
